Surgical pathology report (de-identified scan), TCGA case TCGA-RW-A681, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Michigan University, specimen TCGA-RW-A681-01A (Primary Tumor).

PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:

PATIENT NBR:

PAGE #:
SEX: M

ACCESSION:

OPER DATE:

REQ DOC:

PROCEDURE: SPS

VERIFIED BY:

Source of Specimen: Abdomen. Patient with right adrenal pheochromocytoma.

PROCEDURE: SPGD

VERIFIED BY:

1. "Right adrenal gland." Received in formalin in a large container is a 180 gram, previously incised mass attached to minimal residual adrenal gland. The entire specimen measures 9.4 x 5.5 x 4.5 cm. The mass itself measures 7.2 x 6.9 x 3.5 cm and appears to be arising from the adrenal medulla. Cut surfaces are soft, spongy, yellow to brown. Cut surfaces are heterogeneous, lobular white to focally hemorrhagic and necrotic. The adjacent adrenal gland has a bright orange cortex and a brown medulla. Representative sections of mass submitted in cassettes 1A through D. Representative sections of lesion to normal adrenal in 1E and F.

PROCEDURE: SPDX

VERIFIED BY:

1. Right adrenal, resection: Pheochromocytoma.

I, _____, the signing staff pathologist, have personally examined and interpreted the slides from this case.

** END OF PREVIOUS DIAGNOSIS INQUIRY **

Source: NCI Genomic Data Commons file 87d23599-a32c-47b3-adc8-1bc409792c82 (TCGA-RW-A681.577D0732-CF33-4DAF-9716-F5B96C21BB90.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).